Somatic mutation profile of tumor specimen MP2PRT-PASJZB-TMP1-A (aliquot MP2PRT-PASJZB-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASJZB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (894 days).
Specimen MP2PRT-PASJZB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf169ca2-f9b0-46bf-b560-ff4a242b4b6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASJZB-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASJZB-NB1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28d0f979-07bc-423b-af98-97e37f544c04

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Nonsense Mutation 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 109/464 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSMD2 | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1260407987, COSV53891820; called by muse, mutect2, varscan2
- DHX8 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 99/523 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs763988286; called by muse, mutect2, varscan2
- FHOD3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs769863952, COSV57176444; called by muse, mutect2
- HTR1B | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 112/601 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.372); catalogued as rs754049228; called by muse, mutect2, varscan2
- KIF1A | c.2659G>A p.V887I | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as rs1355031628, COSV100239960, COSV100242133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM8 | c.1508C>T p.T503M | Missense Mutation (SNP) | VAF 124/460 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as rs149254613; called by muse, mutect2, varscan2
- BTBD7 | c.1366del p.L456Yfs*12 | Frame Shift Del (DEL) | VAF 50/287 reads (17%) | called by pindel, varscan2
- CSMD3 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 90/495 reads (18%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZDHHC11 | c.203G>A p.W68* | Nonsense Mutation (SNP) | VAF 76/264 reads (29%) | called by muse, mutect2, varscan2
- FSHR | c.1458T>A p.A486= | Silent (SNP) | VAF 132/477 reads (28%) | called by muse, mutect2, varscan2
- MMP24 | c.984C>A p.P328= | Silent (SNP) | VAF 88/347 reads (25%) | catalogued as rs754781833; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins GGGTA | 3'Flank (INS) | VAF 40/170 reads (24%) | called by pindel, varscan2
